Somatic mutation profile of tumor specimen 0DKMG6 from CCDI case PBBYGE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.5 years (3,836 days).
Specimen 0DKMG6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ac054b9-f4b0-4bc9-8213-4638f756a2af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKMFY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4168e4e-e7a7-4abb-9cd5-4f7e4496c980

The open-access MAF lists 49 somatic variants for this specimen: 33 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, 5'UTR 4, Nonsense Mutation 4, Splice Site 3, 3'UTR 3, Intron 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BIRC5 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 74/1660 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV56957527; called by muse, mutect2
- FSTL3 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1253076953; called by muse, mutect2
- NLRP13 | c.3102G>T p.K1034N | Missense Mutation (SNP) | VAF 111/929 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as rs748807259, COSV100737954, COSV61623619; called by muse, mutect2, varscan2
- PIGA | c.904G>T p.G302* | Nonsense Mutation (SNP) | VAF 58/1510 reads (4%) | catalogued as COSV61237499; called by muse, mutect2
- PIGA | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 71/1335 reads (5%) | catalogued as COSV61237159; called by muse, mutect2
- TAS2R60 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 136/1083 reads (13%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.738); catalogued as COSV60330094; called by mutect2, varscan2
- TLR3 | c.2092del p.D698Tfs*10 | Frame Shift Del (DEL) | VAF 442/1084 reads (41%) | catalogued as COSV57169558; called by mutect2, varscan2
- ADAM9 | c.1130C>G p.S377W | Missense Mutation (SNP) | VAF 247/926 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ARPP19 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 72/1170 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- CCDC169 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 186/568 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD2 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 285/760 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CEP76 | c.634T>C p.F212L | Missense Mutation (SNP) | VAF 396/976 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLEC17A | c.43+1G>T p.X15_splice | Splice Site (SNP) | VAF 59/482 reads (12%) | called by muse, mutect2, varscan2
- CPNE9 | c.1213T>A p.F405I | Missense Mutation (SNP) | VAF 231/578 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EVPL | c.1500G>T p.K500N | Missense Mutation (SNP) | VAF 158/1896 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- FAM183A | c.297+1G>A p.X99_splice | Splice Site (SNP) | VAF 64/1056 reads (6%) | called by muse, mutect2
- HNRNPUL1 | c.290G>C p.G97A | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KIAA1671 | c.5328G>T p.M1776I | Missense Mutation (SNP) | VAF 34/1143 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- MEIS2 | c.305C>T p.T102I (on ENST00000561208 / NM_170675.5; = p.T89I on NM_002399.3) | Missense Mutation (SNP) | VAF 94/632 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- MS4A4A | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 31/918 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2
- NAGLU | c.1075C>T p.Q359* | Nonsense Mutation (SNP) | VAF 337/920 reads (37%) | called by muse, mutect2, varscan2
- NME8 | c.745A>T p.N249Y | Missense Mutation (SNP) | VAF 527/1353 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCNX2 | c.6382G>C p.A2128P | Missense Mutation (SNP) | VAF 44/1824 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- PLCB2 | c.2981A>C p.Q994P | Missense Mutation (SNP) | VAF 228/526 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PLD1 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 113/1984 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PLEKHJ1 | c.95-8G>T | Splice Region (SNP) | VAF 32/216 reads (15%) | called by mutect2, varscan2
- PPP1R3F | c.1850G>A p.W617* | Nonsense Mutation (SNP) | VAF 35/810 reads (4%) | called by muse, mutect2
- SLC6A16 | c.1688G>C p.R563T | Missense Mutation (SNP) | VAF 313/729 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TJP3 | c.2657+1G>T p.X886_splice | Splice Site (SNP) | VAF 38/682 reads (6%) | called by muse, mutect2
- TLN2 | c.6292G>A p.A2098T | Missense Mutation (SNP) | VAF 47/1558 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- TTC16 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 315/763 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TTC25 | c.1652A>G p.D551G | Missense Mutation (SNP) | VAF 32/999 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.111); called by muse, mutect2
- ZSCAN10 | c.2093C>A p.S698Y (on ENST00000252463; = p.S753Y on NM_032805.3) | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CYB5R4 | c.894A>G p.P298= | Silent (SNP) | VAF 533/1423 reads (37%) | called by muse, mutect2, varscan2
- MRPL33 | c.66C>T p.S22= | Silent (SNP) | VAF 282/704 reads (40%) | catalogued as rs765268333; called by muse, mutect2, varscan2
- PLEKHA4 | c.138G>A p.A46= | Silent (SNP) | VAF 369/946 reads (39%) | catalogued as rs761832474; called by muse, mutect2
- PTK2 | c.750C>G p.V250= | Silent (SNP) | VAF 88/2712 reads (3%) | called by muse, mutect2
- WDFY4 | c.1650T>A p.I550= | Silent (SNP) | VAF 74/1403 reads (5%) | called by muse, mutect2
- YAE1 | c.447G>A p.E149= | Silent (SNP) | VAF 126/1679 reads (8%) | catalogued as COSV56233303; called by muse, mutect2
- ZNF646 | c.168C>A p.G56= | Silent (SNP) | VAF 48/460 reads (10%) | called by muse, mutect2, varscan2
- ATAD2 | c.-50G>C | 5'UTR (SNP) | VAF 67/161 reads (42%) | catalogued as rs759552817; called by muse, mutect2, varscan2
- CAMTA1 | c.234+62582G>C | Intron (SNP) | VAF 26/330 reads (8%) | called by muse, mutect2
- DNAJB7 | c.-83A>G | 5'UTR (SNP) | VAF 135/303 reads (45%) | called by muse, mutect2, varscan2
- FAM9B | c.-79C>T | 5'UTR (SNP) | VAF 32/387 reads (8%) | catalogued as rs267606528; called by muse, mutect2
- GABPA | c.-3G>T | 5'UTR (SNP) | VAF 62/1668 reads (4%) | called by muse, mutect2
- HDHD3 | c.*40A>T | 3'UTR (SNP) | VAF 101/231 reads (44%) | called by muse, mutect2, varscan2
- HOPX | c.145-52A>C | Intron (SNP) | VAF 93/239 reads (39%) | called by muse, mutect2, varscan2
- MAGEA1 | c.*10G>T | 3'UTR (SNP) | VAF 20/538 reads (4%) | catalogued as rs782477203; called by muse, mutect2
- SLC17A2 | c.*89C>G | 3'UTR (SNP) | VAF 92/1425 reads (6%) | called by muse, mutect2
